Somatic mutation profile of tumor specimen ALCH-AEUR-TTP1-A (aliquot ALCH-AEUR-TTP1-A-1-0-D-A636-36) from ALCHEMIST case ALCH-AEUR, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 70.5 years (25,767 days).
Specimen ALCH-AEUR-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 442717a2-8f3d-4abd-be62-57dd9e85e093.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AEUR-NB1-A (Blood Derived Normal), aliquot ALCH-AEUR-NB1-A-2-0-D-A635-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/746c4268-2bae-40d5-ad79-a58737afbd53

The open-access MAF lists 188 somatic variants for this specimen: 123 protein-altering or splice-affecting, 45 silent, 20 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 111, Silent 45, Intron 9, Nonsense Mutation 7, RNA 5, 3'UTR 4, Splice Site 3, 5'UTR 1, Frame Shift Ins 1, Frame Shift Del 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAM19 | c.1765G>A p.A589T | Missense Mutation (SNP) | VAF 28/232 reads (12%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.999); catalogued as rs747691760, COSV57424621; called by muse, mutect2, varscan2
- ATP7B | c.1391G>T p.G464V | Missense Mutation (SNP) | VAF 101/524 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV99667024; called by muse, mutect2, varscan2
- BAALC | c.316C>A p.P106T (on ENST00000297574 / NM_001364874.1; = p.P71T on NM_024812.3) | Missense Mutation (SNP) | VAF 28/298 reads (9%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.563); catalogued as COSV99883230; called by muse, mutect2
- C6orf118 | c.533G>T p.R178L | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV100024278; called by muse, mutect2
- CLCF1 | c.377C>G p.T126S | Missense Mutation (SNP) | VAF 17/126 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.046); catalogued as COSV56862165; called by muse, mutect2, varscan2
- CNTN5 | c.199C>A p.P67T | Missense Mutation (SNP) | VAF 51/1263 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.027); catalogued as COSV54347878; called by muse, mutect2
- COL11A1 | c.2764G>T p.G922* | Nonsense Mutation (SNP) | VAF 54/682 reads (8%) | catalogued as COSV62177368; called by muse, mutect2
- COL11A1 | c.893C>T p.T298M | Missense Mutation (SNP) | VAF 74/866 reads (9%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.985); catalogued as rs398123652; ClinVar: uncertain significance; called by muse, mutect2
- CSMD1 | c.10658G>T p.R3553M (on ENST00000520002; = p.R3552M on NM_033225.6) | Missense Mutation (SNP) | VAF 36/316 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as rs532409447; called by muse, mutect2, varscan2
- CSMD1 | c.4361G>T p.G1454V (on ENST00000520002; = p.G1453V on NM_033225.6) | Missense Mutation (SNP) | VAF 19/228 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100147680, COSV59333064; called by muse, mutect2
- DIP2C | c.1029C>G p.N343K | Missense Mutation (SNP) | VAF 19/167 reads (11%) | SIFT tolerated (0.4); PolyPhen benign (0.055); catalogued as COSV55153455; called by muse, mutect2, varscan2
- DLC1 | c.610G>C p.D204H | Missense Mutation (SNP) | VAF 23/296 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.319); catalogued as rs1451094940; called by muse, mutect2
- ERICH3 | c.4184G>T p.G1395V | Missense Mutation (SNP) | VAF 35/409 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as COSV58612261; called by muse, mutect2
- HMX1 | c.473G>T p.G158V | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.147); catalogued as rs1352728207; called by muse, mutect2, varscan2
- KCTD4 | c.493A>G p.I165V | Missense Mutation (SNP) | VAF 15/458 reads (3%) | SIFT deleterious (0.04); PolyPhen benign (0.071); catalogued as rs1310926572; called by muse, mutect2
- LIFR | c.356G>C p.G119A | Missense Mutation (SNP) | VAF 31/246 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV54695092; called by muse, mutect2, varscan2
- MAP4K2 | c.2042A>G p.H681R | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT tolerated (0.34); PolyPhen benign (0.054); catalogued as rs1324395422; called by muse, mutect2
- MAX | c.106A>G p.R36G | Missense Mutation (SNP) | VAF 91/783 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52418001; called by muse, mutect2, varscan2
- NKD2 | c.618G>T p.E206D | Missense Mutation (SNP) | VAF 27/254 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.011); catalogued as rs1341369538; called by muse, mutect2, varscan2
- OR2T34 | c.432G>T p.R144S | Missense Mutation (SNP) | VAF 14/206 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.142); catalogued as rs748312087; called by muse, mutect2
- OR51V1 | c.415C>A p.L139M | Missense Mutation (SNP) | VAF 38/476 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV58316082; called by muse, mutect2
- OR8B12 | c.711T>A p.F237L | Missense Mutation (SNP) | VAF 36/522 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100172750; called by muse, mutect2
- PLCXD3 | c.704A>G p.E235G | Missense Mutation (SNP) | VAF 38/542 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.055); catalogued as rs1434158511; called by muse, mutect2
- PNPLA8 | c.1471A>T p.M491L | Missense Mutation (SNP) | VAF 55/611 reads (9%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.487); catalogued as rs774961886; called by muse, mutect2
- RETREG3 | c.890A>G p.N297S | Missense Mutation (SNP) | VAF 34/415 reads (8%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.996); catalogued as rs756408849; called by muse, mutect2
- RIN1 | c.1180C>T p.P394S | Missense Mutation (SNP) | VAF 24/384 reads (6%) | SIFT tolerated (0.71); PolyPhen benign (0.001); catalogued as rs775005830; called by muse, mutect2
- RSPH14 | c.455C>A p.S152Y | Missense Mutation (SNP) | VAF 22/193 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.254); catalogued as COSV53272620; called by muse, mutect2, varscan2
- SAMD14 | c.884C>A p.P295H (on ENST00000330175 / NM_001257359.2; = p.P323H on NM_174920.4) | Missense Mutation (SNP) | VAF 17/182 reads (9%) | SIFT tolerated (0.57); PolyPhen benign (0.094); catalogued as COSV99142949; called by muse, mutect2
- SERPINB10 | c.1043G>A p.G348D | Missense Mutation (SNP) | VAF 26/352 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs773141164; called by muse, mutect2
- SLC1A5 | c.940G>A p.A314T | Missense Mutation (SNP) | VAF 9/126 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.013); catalogued as rs1244808424; called by muse, mutect2
- SLC4A10 | c.385G>A p.G129S | Missense Mutation (SNP) | VAF 43/491 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as COSV99765163; called by muse, mutect2
- SPANXN3 | c.31G>T p.E11* | Nonsense Mutation (SNP) | VAF 36/198 reads (18%) | catalogued as COSV100980757; called by muse, varscan2
- SPATA31E1 | c.2867G>T p.R956M | Missense Mutation (SNP) | VAF 18/256 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.487); catalogued as COSV57793119; called by muse, mutect2
- TBX21 | c.756C>A p.N252K | Missense Mutation (SNP) | VAF 14/220 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as rs1567921179, COSV51595843; called by muse, mutect2
- TMEM225B | c.46A>G p.I16V | Missense Mutation (SNP) | VAF 44/348 reads (13%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.012); catalogued as rs1437126847; called by muse, mutect2, varscan2
- TMEM272 | c.416A>G p.Q139R | Missense Mutation (SNP) | VAF 20/506 reads (4%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs1285314182; called by muse, mutect2
- TRIML2 | c.611C>A p.A204E | Missense Mutation (SNP) | VAF 31/330 reads (9%) | SIFT tolerated (1); PolyPhen possibly damaging (0.549); catalogued as COSV100455895; called by muse, mutect2
- TSPAN2 | c.110G>T p.R37L | Missense Mutation (SNP) | VAF 39/599 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs760403770; called by muse, mutect2
- ZEB2 | c.2590T>A p.F864I | Missense Mutation (SNP) | VAF 22/302 reads (7%) | SIFT tolerated (0.32); PolyPhen benign (0.052); catalogued as COSV100355723; called by muse, mutect2
- ZIC4 | c.322G>T p.A108S | Missense Mutation (SNP) | VAF 15/195 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.049); catalogued as rs1324177995, COSV67172967; called by muse, mutect2
- ADAMTS13 | c.2078G>T p.G693V | Missense Mutation (SNP) | VAF 14/173 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- ADAMTS9 | c.4069G>T p.D1357Y | Missense Mutation (SNP) | VAF 46/568 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ANK1 | c.1702-1G>A p.X568_splice | Splice Site (SNP) | VAF 4/42 reads (10%) | called by muse, mutect2
- ANO7 | c.715_716+20del p.X239_splice (on ENST00000274979; = p.X185_splice on NM_001370694.2) | Splice Site (DEL) | VAF 12/106 reads (11%) | called by mutect2, pindel
- ARHGAP22 | c.106G>T p.G36C | Missense Mutation (SNP) | VAF 32/368 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.527); called by muse, mutect2
- ASXL3 | c.3716C>A p.S1239Y | Missense Mutation (SNP) | VAF 24/252 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.87); called by muse, mutect2
- C10orf71 | c.2224G>T p.D742Y | Missense Mutation (SNP) | VAF 46/494 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- C2orf16 | c.709G>C p.A237P | Missense Mutation (SNP) | VAF 25/224 reads (11%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- C4orf54 | c.3985G>T p.G1329C | Missense Mutation (SNP) | VAF 13/130 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, varscan2
- C9orf72 | c.739-1G>T p.X247_splice | Splice Site (SNP) | VAF 23/211 reads (11%) | called by muse, mutect2, varscan2
- CCDC113 | c.356G>A p.R119K | Missense Mutation (SNP) | VAF 17/342 reads (5%) | SIFT tolerated (0.92); PolyPhen benign (0.091); called by muse, mutect2
- CCDC59 | c.120C>A p.N40K | Missense Mutation (SNP) | VAF 32/290 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- CELSR2 | c.4970T>C p.I1657T | Missense Mutation (SNP) | VAF 13/142 reads (9%) | SIFT tolerated (0.7); PolyPhen benign (0.005); called by muse, mutect2
- CHEK1 | c.661T>A p.W221R | Missense Mutation (SNP) | VAF 33/297 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- CIDEC | c.568T>C p.W190R | Missense Mutation (SNP) | VAF 36/410 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.936); called by muse, mutect2
- CLDN25 | c.61T>A p.W21R | Missense Mutation (SNP) | VAF 25/162 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- COL18A1 | c.2356C>A p.P786T (on ENST00000359759 / NM_130444.3; = p.P551T on NM_030582.4) | Missense Mutation (SNP) | VAF 12/168 reads (7%) | SIFT tolerated (0.4); PolyPhen benign (0.146); called by muse, mutect2
- CSMD3 | c.9856T>G p.C3286G (on ENST00000297405 / NM_001363185.1; = p.C3117G on NM_052900.3) | Missense Mutation (SNP) | VAF 43/483 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- DIP2C | c.145C>T p.P49S | Missense Mutation (SNP) | VAF 7/133 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.081); called by muse, mutect2
- DNASE2B | c.179G>A p.G60E | Missense Mutation (SNP) | VAF 22/232 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- ERICH3 | c.4183G>T p.G1395* | Nonsense Mutation (SNP) | VAF 36/419 reads (9%) | called by muse, mutect2
- FAM124B | c.1056C>G p.N352K | Missense Mutation (SNP) | VAF 96/822 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- FANCI | c.701T>A p.I234K | Missense Mutation (SNP) | VAF 60/771 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.012); called by muse, mutect2
- FBXO4 | c.604G>T p.E202* | Nonsense Mutation (SNP) | VAF 24/339 reads (7%) | called by muse, mutect2
- FGF10 | c.536C>A p.A179E | Missense Mutation (SNP) | VAF 60/532 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- GABRB2 | c.158C>A p.P53Q | Missense Mutation (SNP) | VAF 28/320 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2
- GJA4 | c.697T>C p.C233R | Missense Mutation (SNP) | VAF 15/147 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.28); called by muse, mutect2, varscan2
- GOLGA1 | c.544A>T p.S182C | Missense Mutation (SNP) | VAF 32/484 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); called by muse, mutect2
- GPR132 | c.959C>T p.S320F | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT tolerated (0.65); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- GRK6 | c.685G>T p.A229S | Missense Mutation (SNP) | VAF 22/323 reads (7%) | SIFT tolerated (0.42); PolyPhen benign (0.003); called by muse, mutect2
- HSPG2 | c.1645G>A p.D549N | Missense Mutation (SNP) | VAF 38/422 reads (9%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.866); called by muse, mutect2
- IFI30 | c.680A>G p.Q227R | Missense Mutation (SNP) | VAF 34/456 reads (7%) | SIFT tolerated (0.25); PolyPhen benign (0.005); called by muse, mutect2
- INHBE | c.145C>G p.Q49E | Missense Mutation (SNP) | VAF 40/436 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.149); called by muse, mutect2
- JAKMIP1 | c.783G>T p.K261N | Missense Mutation (SNP) | VAF 44/380 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- JPH3 | c.73C>G p.H25D | Missense Mutation (SNP) | VAF 38/390 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- KANK4 | c.244C>A p.P82T | Missense Mutation (SNP) | VAF 15/160 reads (9%) | SIFT tolerated (0.33); PolyPhen benign (0.006); called by muse, mutect2
- KAT6B | c.2850G>T p.K950N | Missense Mutation (SNP) | VAF 23/429 reads (5%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.631); called by muse, mutect2
- KCNC2 | c.536C>A p.P179H | Missense Mutation (SNP) | VAF 9/98 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.163); called by muse, mutect2
- KDM4C | c.1030G>C p.D344H | Missense Mutation (SNP) | VAF 40/384 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- KLK4 | c.419A>G p.Q140R | Missense Mutation (SNP) | VAF 46/372 reads (12%) | SIFT tolerated (0.66); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- LATS2 | c.2249G>T p.G750V | Missense Mutation (SNP) | VAF 24/501 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- LCE2D | c.190T>C p.C64R | Missense Mutation (SNP) | VAF 23/364 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.233); called by muse, mutect2
- LCOR | c.641C>T p.A214V | Missense Mutation (SNP) | VAF 22/432 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.012); called by muse, mutect2
- MAGI1 | c.2083C>T p.Q695* | Nonsense Mutation (SNP) | VAF 20/290 reads (7%) | called by muse, mutect2
- METTL14 | c.898A>T p.T300S | Missense Mutation (SNP) | VAF 57/559 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.658); called by muse, mutect2, varscan2
- MYBPC3 | c.650G>T p.S217I | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- MYO7A | c.5908A>G p.T1970A | Missense Mutation (SNP) | VAF 24/372 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.081); called by muse, mutect2
- NCKIPSD | c.871G>T p.G291C | Missense Mutation (SNP) | VAF 38/414 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.319); called by muse, mutect2
- NELL1 | c.2223A>T p.L741F | Missense Mutation (SNP) | VAF 33/436 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.001); called by muse, mutect2
- NES | c.601G>A p.E201K | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- NKD2 | c.619G>T p.E207* | Nonsense Mutation (SNP) | VAF 24/241 reads (10%) | called by mutect2, varscan2
- NUP214 | c.4469G>T p.G1490V | Missense Mutation (SNP) | VAF 34/308 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- OR10K1 | c.780A>T p.L260F | Missense Mutation (SNP) | VAF 30/358 reads (8%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); called by muse, mutect2
- OR11H4 | c.797T>A p.M266K | Missense Mutation (SNP) | VAF 15/141 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- OR1C1 | c.473T>A p.L158Q | Missense Mutation (SNP) | VAF 69/396 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- OR2F1 | c.221C>A p.A74D | Missense Mutation (SNP) | VAF 25/251 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR2M2 | c.819G>A p.M273I | Missense Mutation (SNP) | VAF 64/752 reads (9%) | SIFT tolerated (0.28); PolyPhen benign (0.034); called by muse, mutect2
- OR6K3 | c.892C>A p.P298T (on ENST00000368146; = p.P282T on NM_001005327.2) | Missense Mutation (SNP) | VAF 25/560 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- OR8B12 | c.712A>G p.S238G | Missense Mutation (SNP) | VAF 36/530 reads (7%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.648); called by muse, mutect2
- OTOP1 | c.1048T>C p.F350L | Missense Mutation (SNP) | VAF 38/533 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2
- PCDHGA10 | c.1964A>T p.Q655L | Missense Mutation (SNP) | VAF 56/433 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- PCDHGA4 | c.1349A>T p.N450I | Missense Mutation (SNP) | VAF 24/227 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- PCLO | c.9018del p.Y3007Ifs*17 | Frame Shift Del (DEL) | VAF 42/330 reads (13%) | called by mutect2, pindel, varscan2
- PDE10A | c.2351C>A p.A784E | Missense Mutation (SNP) | VAF 42/398 reads (11%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PROM2 | c.1920_1921insA p.E641Rfs*88 | Frame Shift Ins (INS) | VAF 21/193 reads (11%) | called by mutect2, pindel, varscan2
- PRR32 | c.106T>A p.C36S | Missense Mutation (SNP) | VAF 24/260 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.033); called by muse, mutect2
- PRUNE2 | c.7367C>G p.A2456G | Missense Mutation (SNP) | VAF 24/372 reads (6%) | SIFT tolerated (0.25); PolyPhen benign (0.014); called by muse, mutect2
- PTPRD | c.3205C>A p.Q1069K | Missense Mutation (SNP) | VAF 45/294 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RAB6B | c.202G>T p.D68Y | Missense Mutation (SNP) | VAF 25/169 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SETD5 | c.3583G>T p.G1195* | Nonsense Mutation (SNP) | VAF 23/376 reads (6%) | called by muse, mutect2
- SIK2 | c.502A>G p.K168E | Missense Mutation (SNP) | VAF 35/344 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.16); called by muse, mutect2, varscan2
- SLCO4C1 | c.1447G>T p.G483C | Missense Mutation (SNP) | VAF 17/164 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- STRBP | c.200A>G p.D67G | Missense Mutation (SNP) | VAF 20/170 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2
- TGIF2LX | c.554G>C p.G185A | Missense Mutation (SNP) | VAF 77/510 reads (15%) | SIFT tolerated (0.91); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TMPRSS11F | c.1154G>C p.C385S | Missense Mutation (SNP) | VAF 26/237 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TNS4 | c.1883G>A p.G628D | Missense Mutation (SNP) | VAF 18/136 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- UGT2B15 | c.209C>A p.S70Y | Missense Mutation (SNP) | VAF 20/261 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); called by muse, mutect2
- USP47 | c.1735C>T p.P579S (on ENST00000399455 / NM_001372095.1; = p.P491S on NM_017944.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 35/365 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, varscan2
- WHRN | c.1376T>G p.L459R | Missense Mutation (SNP) | VAF 31/362 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- ZBED1 | c.1531G>C p.G511R | Missense Mutation (SNP) | VAF 17/214 reads (8%) | SIFT tolerated (0.42); PolyPhen benign (0.144); called by muse, mutect2
- ZFAT | c.2117C>T p.P706L | Missense Mutation (SNP) | VAF 30/451 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.015); called by muse, mutect2
- ZNF595 | c.1092A>C p.E364D | Missense Mutation (SNP) | VAF 16/160 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.636); called by muse, mutect2
- ZNF672 | c.1069C>T p.H357Y | Missense Mutation (SNP) | VAF 12/242 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ADAMTS17 | c.1608G>T p.T536= | Silent (SNP) | VAF 15/166 reads (9%) | catalogued as COSV51476998, COSV51485401, COSV99170424; called by muse, mutect2
- AL121899.2 | c.1833G>T p.L611= | Silent (SNP) | VAF 34/281 reads (12%) | called by muse, mutect2, varscan2
- ANK2 | c.1251G>A p.L417= | Silent (SNP) | VAF 100/1056 reads (9%) | called by muse, mutect2
- ANLN | c.1719A>G p.L573= | Silent (SNP) | VAF 51/620 reads (8%) | called by muse, mutect2
- BARHL1 | c.804T>C p.V268= | Silent (SNP) | VAF 22/256 reads (9%) | called by muse, mutect2
- C19orf67 | c.984C>A p.T328= | Silent (SNP) | VAF 16/103 reads (16%) | called by muse, mutect2, varscan2
- CAVIN1 | c.537A>G p.P179= | Silent (SNP) | VAF 28/356 reads (8%) | catalogued as rs968331945; called by muse, mutect2
- CD8B | c.280C>A p.R94= | Silent (SNP) | VAF 52/473 reads (11%) | catalogued as COSV58924933; called by muse, mutect2, varscan2
- CDH3 | c.2061C>T p.L687= | Silent (SNP) | VAF 20/520 reads (4%) | catalogued as rs1567457224; ClinVar: uncertain significance; called by muse, mutect2
- CEP164 | c.2175C>T p.L725= | Silent (SNP) | VAF 48/679 reads (7%) | called by muse, mutect2
- COL21A1 | c.1797A>C p.G599= | Silent (SNP) | VAF 40/473 reads (8%) | called by muse, mutect2
- COL4A1 | c.2796T>A p.P932= | Silent (SNP) | VAF 71/703 reads (10%) | called by muse, mutect2, varscan2
- DOCK5 | c.3324C>T p.P1108= | Silent (SNP) | VAF 22/247 reads (9%) | called by muse, mutect2
- F5 | c.640C>T p.L214= | Silent (SNP) | VAF 68/725 reads (9%) | called by muse, mutect2
- HEATR5B | c.6147G>T p.A2049= | Silent (SNP) | VAF 40/348 reads (11%) | called by muse, mutect2, varscan2
- HFE | c.6C>A p.G2= | Silent (SNP) | VAF 30/248 reads (12%) | called by muse, mutect2, varscan2
- KRAS | c.33T>C p.A11= | Silent (SNP) | VAF 50/506 reads (10%) | catalogued as rs397517039, COSV55688436; ClinVar: likely benign; called by muse, mutect2
- KRTAP11-1 | c.304C>A p.R102= | Silent (SNP) | VAF 54/714 reads (8%) | called by muse, mutect2
- LCE1B | c.42C>A p.P14= | Silent (SNP) | VAF 25/344 reads (7%) | called by muse, mutect2
- LPL | c.1122G>A p.E374= | Silent (SNP) | VAF 34/332 reads (10%) | catalogued as CM110752; called by muse, mutect2, varscan2
- LRRC53 | c.229C>T p.L77= | Silent (SNP) | VAF 70/704 reads (10%) | catalogued as rs570291675; called by muse, mutect2
- LUZP2 | c.405C>T p.S135= | Silent (SNP) | VAF 37/343 reads (11%) | called by muse, mutect2, varscan2
- MYLK2 | c.870G>T p.A290= | Silent (SNP) | VAF 46/361 reads (13%) | called by muse, mutect2, varscan2
- MYOC | c.1293C>A p.I431= | Silent (SNP) | VAF 68/942 reads (7%) | called by muse, mutect2
- NKX3-2 | c.597G>T p.P199= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as rs751612349; called by muse, mutect2, varscan2
- NLRP14 | c.3186G>T p.L1062= | Silent (SNP) | VAF 62/846 reads (7%) | called by muse, mutect2
- NPC1 | c.906C>T p.Y302= | Silent (SNP) | VAF 54/870 reads (6%) | called by muse, mutect2
- OR2M3 | c.891G>T p.V297= | Silent (SNP) | VAF 18/372 reads (5%) | called by muse, mutect2
- OR5P2 | c.246G>C p.L82= | Silent (SNP) | VAF 61/581 reads (10%) | called by muse, mutect2, varscan2
- PCDHB4 | c.1875C>A p.T625= | Silent (SNP) | VAF 36/520 reads (7%) | catalogued as COSV99521773; called by muse, mutect2
- PCDHGB7 | c.402G>T p.R134= | Silent (SNP) | VAF 72/633 reads (11%) | called by muse, mutect2, varscan2
- PPP6R3 | c.528A>G p.P176= | Silent (SNP) | VAF 28/350 reads (8%) | called by muse, mutect2
- RAF1 | c.1131A>C p.L377= | Silent (SNP) | VAF 52/764 reads (7%) | called by muse, mutect2
- RNF141 | c.534T>A p.I178= | Silent (SNP) | VAF 40/419 reads (10%) | called by muse, mutect2
- SERPINB3 | c.366C>A p.A122= | Silent (SNP) | VAF 38/314 reads (12%) | called by muse, varscan2
- SLC1A3 | c.963C>T p.V321= | Silent (SNP) | VAF 64/826 reads (8%) | called by muse, mutect2
- SLC35F3 | c.1245C>T p.A415= (on ENST00000366617 / NM_001300845.1; = p.A484= on NM_173508.4) | Silent (SNP) | VAF 24/291 reads (8%) | called by muse, mutect2
- SNRNP200 | c.1644G>T p.V548= | Silent (SNP) | VAF 41/560 reads (7%) | called by muse, mutect2
- TICAM1 | c.1194G>T p.V398= | Silent (SNP) | VAF 24/330 reads (7%) | called by muse, mutect2
- TRHDE | c.1296G>T p.L432= | Silent (SNP) | VAF 29/315 reads (9%) | called by muse, mutect2
- TRPV4 | c.570G>T p.T190= | Silent (SNP) | VAF 32/464 reads (7%) | catalogued as COSV99925132; called by muse, mutect2
- TTC34 | c.1737G>T p.L579= | Silent (SNP) | VAF 8/112 reads (7%) | called by muse, mutect2
- UBAC1 | c.705G>T p.P235= | Silent (SNP) | VAF 8/77 reads (10%) | called by muse, mutect2
- ZNF99 | c.525T>C p.C175= | Silent (SNP) | VAF 17/163 reads (10%) | catalogued as rs1216652470; called by muse, mutect2, varscan2
- ZSCAN10 | c.324C>T p.P108= (on ENST00000252463; = p.P163= on NM_032805.3) | Silent (SNP) | VAF 14/155 reads (9%) | called by muse, mutect2
- AP000769.3 | chr11:65505454 G>A | 5'Flank (SNP) | VAF 11/89 reads (12%) | catalogued as rs77839640; called by muse, mutect2, varscan2
- BMP7 | c.611+2287C>A | Intron (SNP) | VAF 30/227 reads (13%) | called by muse, mutect2, varscan2
- BSND | c.-16G>T | 5'UTR (SNP) | VAF 19/145 reads (13%) | called by muse, mutect2, varscan2
- EGR1 | c.*221C>T | 3'UTR (SNP) | VAF 10/154 reads (6%) | called by muse, mutect2
- FLJ40288 | n.882C>A | RNA (SNP) | VAF 33/194 reads (17%) | called by muse, mutect2, varscan2
- HOATZ | c.339+8778G>T | Intron (SNP) | VAF 24/240 reads (10%) | catalogued as rs1490284417; called by muse, mutect2
- HYAL4 | c.1045-712C>A | Intron (SNP) | VAF 30/394 reads (8%) | called by muse, mutect2
- KNG1 | c.*1405G>A | 3'UTR (SNP) | VAF 75/664 reads (11%) | called by muse, mutect2, varscan2
- LIMCH1 | c.935+7387G>T | Intron (SNP) | VAF 54/736 reads (7%) | called by muse, mutect2
- LINC02054 | n.2238C>T | RNA (SNP) | VAF 13/175 reads (7%) | catalogued as rs1003231873; called by muse, mutect2
- MAD1L1 | c.1999-22593G>T | Intron (SNP) | VAF 23/269 reads (9%) | called by muse, mutect2
- MARCHF1 | c.-322-85855G>C | Intron (SNP) | VAF 38/602 reads (6%) | catalogued as COSV72277531; called by muse, mutect2
- NPY6R | n.537C>A | RNA (SNP) | VAF 44/372 reads (12%) | catalogued as rs1048959; called by mutect2, varscan2
- ORC4 | c.302-41T>A | Intron (SNP) | VAF 34/302 reads (11%) | called by muse, varscan2
- PLPPR5 | c.*64C>G | 3'UTR (SNP) | VAF 24/368 reads (7%) | called by muse, mutect2
- RIPPLY2 | c.*31G>T | 3'UTR (SNP) | VAF 16/270 reads (6%) | called by muse, mutect2
- SVIL2P | n.1682G>T | RNA (SNP) | VAF 52/479 reads (11%) | called by muse, mutect2, varscan2
- TUBA1B | c.4-654_4-653del | Intron (DEL) | VAF 14/129 reads (11%) | called by pindel, varscan2
- UBTFL2 | n.434C>A | RNA (SNP) | VAF 74/1448 reads (5%) | called by muse, mutect2
- VWA3A | c.351-34C>T | Intron (SNP) | VAF 18/332 reads (5%) | catalogued as rs921333836; called by muse, mutect2
